Somatic mutation profile of tumor specimen TCGA-CR-7377-01A (aliquot TCGA-CR-7377-01A-11D-2012-08) from TCGA case TCGA-CR-7377, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 58.5 years (21,371 days).
Specimen TCGA-CR-7377-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bef8e2a3-6a72-49f0-9e6e-e222fcdb0a67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7377-10A (Blood Derived Normal), aliquot TCGA-CR-7377-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12b924ad-cdab-4f69-8a55-e056ed72aab9

The open-access MAF lists 120 somatic variants for this specimen: 86 protein-altering or splice-affecting, 33 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 33, Nonsense Mutation 5, Splice Site 3, Splice Region 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2675C>T p.S892F | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1330586888, COSV100750879; called by muse, mutect2, varscan2
- ACSL1 | c.1639-1G>A p.X547_splice | Splice Site (SNP) | VAF 50/411 reads (12%) | catalogued as rs111329654, COSV99860719; called by muse, mutect2, varscan2
- AHI1 | c.1082T>C p.I361T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99662998; called by muse, mutect2, varscan2
- ALAS2 | c.1140T>G p.H380Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as COSV100238441; called by muse, mutect2, varscan2
- ANKMY2 | c.1214A>G p.K405R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs753181901, COSV100187142; called by muse, mutect2, varscan2
- AP1B1 | c.407A>T p.Y136F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100434639; called by muse, mutect2, varscan2
- ARID5B | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99689895; called by muse, mutect2, varscan2
- ASF1B | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV99654321; called by muse, mutect2, varscan2
- ATP11C | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558164; called by muse, mutect2, varscan2
- CARS1 | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99542933; called by muse, mutect2, varscan2
- CCDC149 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as COSV100164745, COSV60878450; called by muse, mutect2, varscan2
- CCT8L2 | c.979A>T p.S327C | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV100742838; called by muse, mutect2, varscan2
- CNGB3 | c.1249T>G p.L417V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV60686709; called by muse, mutect2, varscan2
- COL21A1 | c.2390G>A p.C797Y | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99779109; called by muse, mutect2
- CSMD1 | c.194G>C p.G65A | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV101219322, COSV101221712; called by muse, mutect2, varscan2
- DENND1C | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV101200216; called by muse, mutect2, varscan2
- DHX9 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100841449; called by muse, mutect2
- DPPA2 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV101524775, COSV72118156; called by muse, mutect2, varscan2
- ELMO1 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.418); catalogued as rs1267317650, COSV100164892, COSV60320078; called by muse, mutect2, varscan2
- ERCC3 | c.1830A>T p.V610= | Splice Region (SNP) | VAF 8/136 reads (6%) | catalogued as COSV99573427; called by muse, mutect2
- ESPNL | c.2753G>A p.G918D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1448809001, COSV100547847; called by muse, mutect2
- ESYT1 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs202161347, COSV99920049; called by muse, mutect2, varscan2
- GIGYF2 | c.1934A>C p.K645T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs1305145801, COSV101004453; called by muse, mutect2, varscan2
- GMPR2 | c.5C>T p.P2L (on ENST00000355299 / NM_001351022.2; = p.P20L on NM_016576.5) | Missense Mutation (SNP) | VAF 84/451 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99164634; called by muse, mutect2, varscan2
- GOLGB1 | c.5303C>G p.S1768C | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100511104, COSV104415740; called by muse, mutect2
- H2AC20 | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as COSV100480000, COSV58611285; called by muse, mutect2
- H2BC6 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.282); catalogued as rs1486145341, COSV100534443; called by muse, mutect2
- HMCN1 | c.15545G>A p.R5182Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs148826584; called by muse, mutect2, varscan2
- HNRNPL | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99670381; called by muse, mutect2
- IGHMBP2 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.044); catalogued as COSV99662189; called by muse, mutect2, varscan2
- INTS2 | c.1523T>C p.V508A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1412956559, COSV99248329; called by muse, mutect2
- IPO11 | c.1068C>G p.F356L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100321071; called by muse, mutect2, varscan2
- ITGAX | c.2117T>C p.L706P | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99191793; called by muse, mutect2
- KIAA0319 | c.2341C>G p.L781V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100985641; called by muse, mutect2, varscan2
- LPAR6 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99925297; called by muse, mutect2
- LZTR1 | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs1393147910, COSV99301928; called by muse, mutect2
- MISP | c.1573G>T p.V525F | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV99296938; called by muse, mutect2, varscan2
- MITF | c.1087C>T p.R363C (on ENST00000448226 / NM_006722.3; = p.R263C on NM_000248.4) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372113245; called by muse, mutect2, varscan2
- MPPED1 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV100501252, COSV100501259; called by muse, mutect2
- MRC2 | c.1133T>A p.V378E | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100316384; called by muse, mutect2, varscan2
- MUC5AC | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.23); catalogued as rs756236901, COSV100650628; called by muse, mutect2, varscan2
- MYCBPAP | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100088418; called by muse, mutect2, varscan2
- NINL | c.3169G>A p.D1057N | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV99625578; called by muse, mutect2, varscan2
- NOTCH1 | c.6181-1G>A p.X2061_splice | Splice Site (SNP) | VAF 4/29 reads (14%) | catalogued as COSV53028541, COSV99487534; called by muse, mutect2
- NOTCH1 | c.4348G>T p.E1450* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99489207; called by muse, mutect2, varscan2
- NRXN3 | c.325C>T p.R109W (on ENST00000557594 / NM_001272020.2; = p.R741W on NM_004796.6) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55316276, COSV55327182; called by muse, mutect2, varscan2
- NTRK1 | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs532851293, COSV100693495; called by muse, mutect2, varscan2
- PCDHB14 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.292); catalogued as COSV99506024; called by muse, mutect2, varscan2
- PLCH1 | c.161G>A p.R54Q (on ENST00000340059 / NM_001130960.2; = p.R66Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs776740395, COSV58211090; called by muse, mutect2, varscan2
- RNASEL | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100842610; called by muse, mutect2, varscan2
- RNF111 | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs780195378, COSV100789094; called by muse, varscan2
- RTL9 | c.2469G>A p.M823I | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.528); catalogued as COSV101511718; called by muse, mutect2, varscan2
- SCN3B | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100173762; called by muse, mutect2, varscan2
- SH3GL3 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs559656402, COSV61053890, COSV61056992; called by muse, mutect2, varscan2
- SI | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100015341; called by muse, mutect2, varscan2
- SIM1 | c.2111A>G p.Q704R | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.395); catalogued as COSV99492471; called by muse, mutect2, varscan2
- SLITRK2 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV100157880; called by muse, mutect2, varscan2
- SNRNP25 | c.56A>G p.D19G (on ENST00000383018; = p.D10G on NM_024571.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.245); catalogued as rs761819954, COSV51953791, COSV99244801; called by muse, mutect2, varscan2
- SORD | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51042862, COSV99980631; called by muse, mutect2, varscan2
- SPHKAP | c.3425G>C p.R1142T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60868248, COSV60873012; called by muse, mutect2, varscan2
- STEAP4 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV100112611; called by muse, mutect2, varscan2
- STRN4 | c.1898G>A p.G633D | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.198); catalogued as rs1391259189, COSV99623760; called by muse, mutect2, varscan2
- STXBP3 | c.1364A>C p.Q455P | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV100894018; called by muse, mutect2, varscan2
- SULT1C2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV99265261; called by muse, mutect2
- SYT6 | c.746G>A p.R249H (on ENST00000610222 / NM_001366225.1; = p.R164H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs139165674, COSV101059648; called by muse, mutect2, varscan2
- TEX10 | c.2296G>A p.V766I | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs771324835, COSV100887844; called by muse, mutect2, varscan2
- THEM5 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs376299585; called by muse, mutect2, varscan2
- THSD4 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99965933; called by muse, mutect2, varscan2
- TMEM106B | c.281+1G>A p.X94_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | catalogued as rs751818729, COSV67543354; called by muse, mutect2, varscan2
- TMEM200A | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1165804854, COSV99759470; called by muse, mutect2, varscan2
- TPH1 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100000926; called by muse, mutect2, varscan2
- TRIM15 | c.1365G>A p.W455* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100938851; called by muse, mutect2, varscan2
- TRPA1 | c.3050T>C p.F1017S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100084460; called by muse, mutect2
- TTC13 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs200301610; called by muse, mutect2, varscan2
- TUBA1B | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 31/222 reads (14%) | catalogued as COSV100254153; called by muse, mutect2, varscan2
- ZAN | c.3764G>A p.R1255Q | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.535); catalogued as rs376487262; called by muse, mutect2, varscan2
- ZNF276 | c.284C>T p.S95F (on ENST00000443381 / NM_001113525.2; = p.S20F on NM_152287.4) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV99235064; called by muse, mutect2
- ZNF334 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs774723342, COSV61618769; called by muse, mutect2, varscan2
- ZNF503 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100998013; called by muse, mutect2
- ZNF510 | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV99793904; called by muse, mutect2, varscan2
- ZNF676 | c.1056G>C p.W352C (on ENST00000650058; = p.W320C on NM_001001411.3) | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV101236216, COSV101236247; called by muse, mutect2
- ZNF827 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs993072562, COSV101061464; called by muse, mutect2, varscan2
- FRG2C | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 12/303 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.591); called by muse, mutect2
- PGC | c.783_798del p.Q262Vfs*23 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- PLK4 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.07); called by muse, mutect2
- ABI3BP | c.3183G>A p.G1061= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV99427255; called by muse, mutect2
- BTG2 | c.342G>A p.G114= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as rs1368485709, COSV99305829; called by muse, mutect2, varscan2
- CA10 | c.300C>T p.N100= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV99563561; called by muse, mutect2, varscan2
- CD34 | c.1077T>A p.A359= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100178468; called by muse, mutect2
- CRB2 | c.3528C>T p.P1176= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV100749692; called by muse, mutect2
- CRISP3 | c.180T>C p.T60= (on ENST00000371159 / NM_001368123.1; = p.T42= on NM_006061.4) | Silent (SNP) | VAF 23/229 reads (10%) | catalogued as rs769652993, COSV99539012; called by muse, mutect2, varscan2
- DIS3 | c.2733C>A p.I911= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100899922, COSV66707369; called by muse, mutect2, varscan2
- DNAH3 | c.7746G>A p.S2582= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as rs763356860, COSV54521378; called by muse, mutect2, varscan2
- DPPA4 | c.837G>A p.P279= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs370990673; called by muse, mutect2, varscan2
- FAM135A | c.1038A>G p.R346= (on ENST00000370479 / NM_001351599.1; = p.R329= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as COSV99526002; called by muse, mutect2
- FARSA | c.1041G>A p.P347= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as rs530112428; called by muse, mutect2
- FSTL5 | c.2541C>T p.A847= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV100057050; called by muse, mutect2
- GDPD3 | c.198C>T p.R66= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV99531686; called by muse, mutect2
- GLO1 | c.444A>G p.K148= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV100974096; called by muse, mutect2, varscan2
- GOLT1B | c.414A>G p.V138= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV57553503; called by muse, mutect2, varscan2
- HECW1 | c.4209A>G p.L1403= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV101223869; called by muse, mutect2, varscan2
- LRRN1 | c.1206G>C p.P402= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as rs147557425, COSV100076395; called by muse, mutect2, varscan2
- MORC1 | c.1614C>T p.S538= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs760750431, COSV99226594; called by muse, mutect2
- OR5H14 | c.42C>T p.L14= | Silent (SNP) | VAF 22/242 reads (9%) | catalogued as COSV101454213; called by muse, mutect2
- OSGEP | c.516C>T p.N172= | Silent (SNP) | VAF 24/239 reads (10%) | catalogued as rs199582839, COSV99248047; called by muse, mutect2
- PLXNB2 | c.3471G>A p.P1157= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs747767472, COSV100834118; called by muse, mutect2, varscan2
- POU4F3 | c.972C>T p.N324= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs763770511, COSV100047112; called by muse, mutect2
- PTGFRN | c.1029G>A p.S343= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs1415973274, COSV101277221, COSV67799276; called by muse, mutect2, varscan2
- SCN3B | c.105C>T p.A35= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs368979661; ClinVar: likely benign; called by muse, mutect2, varscan2
- SIM1 | c.240G>A p.L80= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV99492472; called by muse, mutect2, varscan2
- SLC8A1 | c.2028C>T p.I676= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100246513; called by muse, mutect2, varscan2
- TAF1 | c.2121A>G p.T707= (on ENST00000373790 / NM_138923.4; = p.T728= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs754466296, COSV99336115; called by muse, mutect2, varscan2
- TMEM19 | c.432A>G p.T144= | Silent (SNP) | VAF 28/161 reads (17%) | catalogued as rs1163697121, COSV99877001; called by muse, mutect2, varscan2
- TRBV27 | c.141C>T p.N47= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- UNC79 | c.5481C>T p.S1827= (on ENST00000393151 / NM_001346218.2; = p.S1650= on NM_020818.5) | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs749708792, COSV99827611; called by muse, mutect2, varscan2
- ZNF318 | c.2238A>G p.P746= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV100546310; called by muse, mutect2, varscan2
- ZNF483 | c.1932C>T p.F644= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100492974; called by muse, mutect2, varscan2
- ZNF831 | c.1239C>T p.S413= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100926093; called by muse, mutect2, varscan2
- ZNF99 | c.*317C>T | 3'UTR (SNP) | VAF 13/99 reads (13%) | catalogued as COSV68054757; called by muse, mutect2, varscan2
